Somatic mutation profile of tumor specimen TCGA-DX-AB3A-01A (aliquot TCGA-DX-AB3A-01A-11D-A417-09) from TCGA case TCGA-DX-AB3A, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 80.0 years (29,230 days).
Specimen TCGA-DX-AB3A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86f09e94-847b-405a-b2b9-03fb25247ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB3A-10A (Blood Derived Normal), aliquot TCGA-DX-AB3A-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d308987-c52c-4325-912b-3aa6630e6880

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.2168A>G p.N723S (on ENST00000404938 / NM_001163941.2; = p.N278S on NM_178559.6) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.096); catalogued as COSV99327287; called by muse, mutect2, varscan2
- ARHGEF11 | c.2275A>G p.I759V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100168193; called by muse, mutect2, varscan2
- ATRX | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 17/17 reads (100%) | catalogued as COSV64878335; called by muse, mutect2, varscan2
- DPY19L3 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100639073; called by muse, mutect2, varscan2
- HMCN1 | c.13693G>T p.G4565W | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99623534; called by muse, mutect2
- IFT80 | c.533A>T p.N178I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100424315; called by muse, mutect2, varscan2
- IRF2BP2 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as rs951448865, COSV100784229; called by muse, mutect2, varscan2
- KIR2DL1 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99382578; called by muse, mutect2, varscan2
- KSR2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs768839138, COSV60376750; called by muse, mutect2, varscan2
- LNPEP | c.2388T>G p.F796L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99183463; called by muse, mutect2, varscan2
- MECR | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs751642810, COSV99746761; called by muse, mutect2, varscan2
- MRPL44 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1241700513, COSV51313081; called by muse, varscan2
- MUC16 | c.16204A>T p.R5402* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV101197868; called by muse, mutect2, varscan2
- OR2T8 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV100178020; called by muse, mutect2, varscan2
- RUNX3 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100136616, COSV58850164; called by muse, mutect2, varscan2
- SALL2 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58102872; called by muse, mutect2, varscan2
- SIGLEC7 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV99978397; called by muse, mutect2, varscan2
- SLC16A10 | c.820A>C p.K274Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100920808; called by muse, mutect2, varscan2
- STEAP2 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV99840200; called by muse, mutect2, varscan2
- TRHDE | c.2872A>G p.N958D | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV53850812; called by muse, mutect2, varscan2
- URB2 | c.3451G>T p.V1151F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV99270578; called by muse, mutect2
- VPS13C | c.5336C>G p.A1779G (on ENST00000644861 / NM_020821.3; = p.A1736G on NM_017684.5) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99826848; called by muse, mutect2, varscan2
- IGHV4-61 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- ISCA1 | c.220_236delinsTCATC p.D74_Q79delinsSS | In Frame Del (DEL) | VAF 34/89 reads (38%) | called by pindel, varscan2*
- PLEC | c.11490_11515del p.G3831Dfs*44 (on ENST00000322810 / NM_201380.4; = p.G3721Dfs*44 on NM_000445.5) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TACR1 | c.363_367del p.S122Dfs*6 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ZNF488 | c.173C>G p.P58R | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.174); called by muse, mutect2
- APBA1 | c.1671G>A p.L557= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99595318; called by muse, mutect2, varscan2
- ASAP3 | c.1404C>T p.H468= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1449103560; called by muse, mutect2, varscan2
- DDX41 | c.636C>T p.I212= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100286355; called by muse, mutect2, varscan2
- EDAR | c.312A>T p.P104= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ERBB3 | c.1251C>T p.T417= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs757695889, COSV99915608; called by muse, mutect2, varscan2
- KIF26A | c.5529C>A p.A1843= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100180693; called by muse, mutect2, varscan2
- LRRIQ1 | c.4509G>A p.L1503= | Silent (SNP) | VAF 995/1049 reads (95%) | catalogued as COSV101279382; called by muse, mutect2, varscan2
- MEI1 | c.2296C>T p.L766= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1031619259, COSV100299500; called by muse, mutect2, varscan2
- NUDT16 | c.258C>A p.A86= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100720799; called by muse, mutect2, varscan2
